Somatic mutation profile of tumor specimen ALCH-ADMX-TTP1-A (aliquot ALCH-ADMX-TTP1-A-1-0-D-A532-36) from ALCHEMIST case ALCH-ADMX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.8 years (17,451 days).
Specimen ALCH-ADMX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b79c8218-e12a-4517-ab4e-a9ca667bdbea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADMX-NB1-A (Blood Derived Normal), aliquot ALCH-ADMX-NB1-A-1-0-D-A532-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fea99db4-888c-4d8d-b673-a93e346f2199

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'UTR 1, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LPA | c.4901G>A p.G1634E | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60297995; called by muse, mutect2, varscan2
- MICAL1 | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs778191728; called by muse, mutect2, varscan2
- NAT9 | c.393C>T p.Y131= | Splice Region (SNP) | VAF 23/232 reads (10%) | catalogued as rs370054214; called by muse, mutect2, varscan2
- ZCCHC12 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1027940742, COSV59572946; called by muse, mutect2
- ATP13A3 | c.2805del p.F936Sfs*25 | Frame Shift Del (DEL) | VAF 33/272 reads (12%) | called by mutect2, pindel, varscan2
- KCTD21 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- LRRC2 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- GP2 | c.687T>C p.C229= (on ENST00000381362 / NM_001007240.3; = p.C226= on NM_001502.4) | Silent (SNP) | VAF 61/323 reads (19%) | called by muse, mutect2, varscan2
- HSP90B1 | c.1722A>G p.E574= | Silent (SNP) | VAF 95/660 reads (14%) | catalogued as COSV55358829; called by muse, mutect2, varscan2
- ACIN1 | c.2298-1882C>T | Intron (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- H6PD | c.*45G>A | 3'UTR (SNP) | VAF 17/94 reads (18%) | catalogued as rs766298635; called by muse, mutect2, varscan2
